Gene-level copy-number profile of tumor specimen TCGA-A2-A1FX-01A from TCGA case TCGA-A2-A1FX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-A2-A1FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a3f4ad97-3d59-4568-84e8-674280b1f04a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1FX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd5dba9f-2202-4c06-a314-8b83cebdc687

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,767; copy number 3: 8,125; copy number 4: 21,711; copy number 5: 11,811; copy number 6: 5,719; copy number 7: 871; copy number 8: 39; copy number 9: 3,289; copy number 10: 357; copy number 12: 10; copy number 14: 72; copy number 16: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A1FX-01A-11D-A13J-01): tumor purity 0.72, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,771 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,821,014–91,404,856, 23 genes, copy number 10 (within-gene range 3–10): LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326, AL161797.1, AC098656.1, RNU6-695P, AL627316.1, LINC02787, SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763, AC091614.1, PHKA1P1, ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1.
- chr1:93,179,919–95,479,356, 57 genes, copy number 10: CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53, BCAR3, BCAR3-AS1, MIR760, AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, AC118469.2, ABCD3, F3, AC093117.1, SLC44A3-AS1, KATNBL1P2, MIR378G, SLC44A3, CNN3, AC105942.1, ALG14, ALG14-AS1, TLCD4, TLCD4-RWDD3, AC092802.3, Y_RNA, AC092802.1, RWDD3, AC092802.2, AC092802.4, LINC01760, LINC01650, AL445218.1, LINC01761.
- chr1:101,639,509–115,698,224, 277 genes, copy number 10 (broad region; genes not listed).
- chr6:167,607–61,241,311, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr8:36,308,245–145,066,685, 1,716 genes, copy number 9 (broad region; genes not listed).
- chr11:44,564,427–45,883,248, 33 genes, copy number 9 (within-gene range 6–9): CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2.
- chr11:69,048,932–70,436,584, 42 genes, copy number 16 (within-gene range 10–16): TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 16: AP001271.1.
- chr11:77,216,558–80,653,988, 53 genes, copy number 14 (within-gene range 2–14): GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3.
- chr11:82,603,529–83,039,115, 10 genes, copy number 12 (within-gene range 2–12): AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2.
- chr11:97,222,644–98,566,827, 6 genes, copy number 9: LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1.
- chr16:35,363,412–35,522,465, 19 genes, copy number 14: LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
